Somatic mutation profile of tumor specimen TARGET-20-PARGYS-09A (aliquot TARGET-20-PARGYS-09A-01D) from TARGET case TARGET-20-PARGYS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 20.6 years (7,532 days).
Specimen TARGET-20-PARGYS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb23a074-03f5-46be-a7a4-1910e10dddb4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARGYS-14A (Bone Marrow Normal), aliquot TARGET-20-PARGYS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b91fb445-7078-4717-828d-417884bcc8b4

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 116/238 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.*345C>A | 3'UTR (SNP) | VAF 100/209 reads (48%) | called by muse, mutect2, varscan2
